CCDI case PBBRKJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ba826436-5832-481e-b472-9b665e7d5c04

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 5.9 years (2,161 days).

Biospecimens (3 samples)
- Sample 0DFBL8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFBLD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFBLQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
